Gene-level copy-number profile of tumor specimen C3N-01764-01 from CPTAC case C3N-01764, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 73.6 years (26,880 days).
Specimen C3N-01764-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e9bf37e3-c945-4e4a-9fda-1bc861cc32d1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01764-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/52ef6a87-1c97-4234-900a-207daafb1a36

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 11,128; copy number 2: 42,833; copy number 3: 3,216; copy number 4: 922; copy number 5: 139; copy number 6: 88; copy number 7: 53; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:50,117,130–50,668,306, 16 genes: SOS2, L2HGDH, MIR4504, DMAC2L, AL359397.2, CDKL1, AL359397.1, MAP4K5, AL118556.1, Y_RNA, AL118556.2, ATL1, SNRPGP1, SAV1, RN7SL452P, AL606834.1.
- chr15:80,344,853–80,597,933, 7 genes: AC016705.2, ARNT2, AC016705.1, AC016705.3, AC108451.1, AC108451.2, MIR5572.
- chr18:75,195,113–75,209,139, 1 gene: ZADH2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 282 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:57,744,495–58,159,555, 17 genes, copy number 5 (within-gene range 3–5): CCDC182, AC015845.2, RN7SKP94, MRPS23, CUEDC1, AC015845.1, AC015813.4, VEZF1, AC015813.7, AC015813.2, AC015813.1, SRSF1, AC015813.5, AC015813.3, DYNLL2, AC015813.6, OR4D1.
- chr17:73,192,632–73,262,352, 6 genes, copy number 5 (within-gene range 3–5): COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L.
- chr19:9,083,112–12,156,734, 187 genes, copy number 5–8 (broad region; genes not listed).
- chr19:17,511,636–17,688,365, 8 genes, copy number 6 (within-gene range 4–6): PGLS, AC010618.2, NIBAN3, COLGALT1, AC010618.1, UNC13A, AC008761.2, AC008761.3.
- chr20:25,006,230–26,251,546, 44 genes, copy number 5–6: ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.
- chr22:20,394,115–20,704,606, 20 genes, copy number 5: ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A.

Autosomal genes at a single copy (total copy number 1): 11,128. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
